Somatic mutation profile of tumor specimen TCGA-BP-5177-01A (aliquot TCGA-BP-5177-01A-01D-1429-08) from TCGA case TCGA-BP-5177, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 46.9 years (17,147 days).
Specimen TCGA-BP-5177-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23320d8c-1691-4b73-a758-bdc49df52918.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5177-11A (Solid Tissue Normal), aliquot TCGA-BP-5177-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/336109a6-4b02-4377-bbf7-3290bb627029

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 10, Frame Shift Del 6, Nonsense Mutation 3, Translation Start Site 1, Intron 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.3317T>C p.V1106A | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV52206775; called by muse, mutect2, varscan2
- ADPRHL1 | c.201G>C p.E67D | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV60261898; called by muse, mutect2, varscan2
- ANKRD13C | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV52033096, COSV52035472; called by muse, mutect2, varscan2
- CABLES1 | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as rs1250089835, COSV56935200; called by muse, mutect2, varscan2
- COP1 | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.945); catalogued as rs746236381, COSV58171316; called by muse, mutect2, varscan2
- DISP3 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 76/332 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs756856438, COSV53828906; called by muse, mutect2, varscan2
- DNAH11 | c.2854C>T p.P952S | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.71); PolyPhen benign (0.03); catalogued as COSV60966588; called by muse, mutect2, varscan2
- EPS8L2 | c.2103G>C p.M701I | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs756437745, COSV59348971; called by mutect2, varscan2
- GALNT1 | c.1274C>A p.P425Q | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52453594; called by muse, mutect2, varscan2
- GFRAL | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 16/452 reads (4%) | catalogued as COSV61233098; called by muse, mutect2
- GNG3 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 22/82 reads (27%) | catalogued as COSV53655341; called by muse, mutect2, varscan2
- HOXD4 | c.51C>G p.F17L | Missense Mutation (SNP) | VAF 41/264 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752396313, COSV60459621, COSV60460364; called by muse, mutect2, varscan2
- IGSF10 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV56788381, COSV99176605; called by muse, mutect2
- MAPKBP1 | c.1558C>A p.H520N (on ENST00000456763 / NM_001128608.2; = p.H514N on NM_014994.3) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52964534; called by muse, mutect2, varscan2
- NCAN | c.224G>T p.R75L | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53047996, COSV53054435; called by muse, mutect2, varscan2
- NCKAP5 | c.3892C>T p.R1298C | Missense Mutation (SNP) | VAF 13/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs891045150, COSV58459416; called by muse, mutect2
- NOL8 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as COSV62636307; called by muse, mutect2, varscan2
- RBM8A | c.295A>C p.I99L | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV57162944; called by muse, mutect2, varscan2
- SMOC1 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs764074930, COSV62762334; called by muse, mutect2, varscan2
- SPIB | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); catalogued as COSV54531844; called by muse, mutect2, varscan2
- SRGAP1 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 26/141 reads (18%) | catalogued as COSV61896315; called by muse, mutect2, varscan2
- TBC1D24 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV53547532; called by muse, mutect2, varscan2
- TSSK6 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as COSV53064444; called by muse, mutect2, varscan2
- VHL | c.389T>A p.V130D | Missense Mutation (SNP) | VAF 83/245 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56542617, COSV56561584; called by muse, mutect2, varscan2
- WNT7B | c.626G>A p.C209Y | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59751197; called by muse, mutect2, varscan2
- ZNF304 | c.37del p.C13Vfs*2 | Frame Shift Del (DEL) | VAF 29/124 reads (23%) | catalogued as COSV99988906; called by mutect2, pindel, varscan2
- ZNF480 | c.1118G>A p.C373Y | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57997125; called by muse, mutect2, varscan2
- ARFGEF3 | c.2397del p.G800Efs*20 | Frame Shift Del (DEL) | VAF 13/74 reads (18%) | called by mutect2, pindel*, varscan2
- ASAH2 | c.1736A>T p.Y579F | Missense Mutation (SNP) | VAF 42/226 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BMS1 | c.2691del p.F897Lfs*30 | Frame Shift Del (DEL) | VAF 31/167 reads (19%) | called by mutect2, pindel, varscan2
- DHX35 | c.1739_1744dup p.T580_V581dup | In Frame Ins (INS) | VAF 72/390 reads (18%) | called by mutect2, varscan2
- FLNB | c.5429_5430del p.S1810Tfs*49 | Frame Shift Del (DEL) | VAF 30/219 reads (14%) | called by mutect2, pindel, varscan2
- TNFSF13 | c.161_162del p.E54Afs*70 | Frame Shift Del (DEL) | VAF 7/45 reads (16%) | called by pindel, varscan2
- UBR7 | c.1028del p.N343Tfs*15 | Frame Shift Del (DEL) | VAF 58/305 reads (19%) | called by mutect2, pindel, varscan2
- CLCA2 | c.1881T>C p.N627= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as rs1231882937, COSV65287599; called by muse, varscan2
- CRYBG1 | c.3519G>A p.P1173= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as rs200098719, COSV64813319; called by muse, mutect2, varscan2
- KCNN3 | c.1632C>T p.I544= (on ENST00000618040 / NM_001204087.1; = p.I529= on NM_002249.6) | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV55221346; called by muse, mutect2, varscan2
- NAV1 | c.1944C>T p.S648= | Silent (SNP) | VAF 43/187 reads (23%) | catalogued as COSV55221401; called by muse, mutect2, varscan2
- NXPH4 | c.816G>A p.K272= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV61073986; called by muse, mutect2, varscan2
- PBDC1 | c.603A>G p.K201= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV64896005; called by muse, mutect2, varscan2
- PLA2G4F | c.393C>T p.D131= | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as COSV51828192; called by muse, mutect2
- TECPR2 | c.1932C>T p.L644= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV63970341; called by muse, mutect2, varscan2
- TIMM44 | c.477G>A p.S159= | Silent (SNP) | VAF 46/166 reads (28%) | catalogued as rs749770608, COSV54493091; called by muse, mutect2, varscan2
- TOB1 | c.93A>G p.E31= | Silent (SNP) | VAF 49/193 reads (25%) | catalogued as COSV52150592, COSV99278889; called by muse, mutect2, varscan2
- KCTD7 | c.453+39del | Intron (DEL) | VAF 21/92 reads (23%) | catalogued as COSV51877113; called by mutect2, pindel*, varscan2
- SNORD115-23 | n.2G>A | RNA (SNP) | VAF 65/330 reads (20%) | called by muse, mutect2, varscan2
